Somatic mutation profile of tumor specimen e8faa3a7-9fc7-428e-9334-a0afd0 (aliquot e8faa3a7-9fc7-428e-9334-a0afd0_D6) from CPTAC case 11CO062, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA.
Specimen e8faa3a7-9fc7-428e-9334-a0afd0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a941f87-e4f9-4e99-826c-2baaaf9abda6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ee8227b3-320c-49ce-9c94-5b0252 (Blood Derived Normal), aliquot ee8227b3-320c-49ce-9c94-5b0252_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1804174e-f8f1-407b-98c0-f92e8ea5849f

The open-access MAF lists 146 somatic variants for this specimen: 86 protein-altering or splice-affecting, 40 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 40, Intron 15, Frame Shift Del 4, Splice Site 3, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 2, 5'Flank 2, RNA 2, Splice Region 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 95/317 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 25/141 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 61/181 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 70/461 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as rs201162234, COSV51097695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMY1A | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.208); catalogued as COSV100915772; called by muse, mutect2
- BMP10 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs141935259; called by muse, mutect2, varscan2
- BMP5 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 62/382 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs768565166, COSV63703116; called by muse, mutect2, varscan2
- CCDC121 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.075); catalogued as COSV53117288; called by muse, mutect2, varscan2
- CDH23 | c.3916G>A p.E1306K | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1007435841, COSV56478456; called by muse, mutect2, varscan2
- CNPY4 | c.738_740del p.E246del | In Frame Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs747967394; called by pindel, varscan2
- COL2A1 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 116/388 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1271100187, CD103304, COSV100477780; called by muse, mutect2, varscan2
- DAW1 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs756173701, COSV59364997; called by muse, mutect2, varscan2
- ERP29 | c.712_714del p.K238del | In Frame Del (DEL) | VAF 40/129 reads (31%) | catalogued as rs1352097022; called by pindel, varscan2
- ERVV-1 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.131); catalogued as rs745614848; called by muse, mutect2, varscan2
- FAM155A | c.601G>T p.G201W | Missense Mutation (SNP) | VAF 15/318 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV65549917, COSV65552280; called by muse, mutect2
- FAM184B | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as rs370211318; called by muse, mutect2, varscan2
- FKBP8 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 55/332 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs375921391; called by muse, mutect2, varscan2
- FLRT2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 75/506 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100420882; called by muse, mutect2, varscan2
- FNDC1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs756842140, COSV51932856; called by muse, mutect2, varscan2
- FPR1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs201404212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR37 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs766183726; called by muse, mutect2, varscan2
- HCK | c.1377A>G p.P459= | Splice Region (SNP) | VAF 30/155 reads (19%) | catalogued as rs1569017304; called by muse, mutect2, varscan2
- HSPB7 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757356294; called by muse, mutect2, varscan2
- HTR2C | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV52201275, COSV52220450; called by muse, mutect2, varscan2
- KANK1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs137938410; called by muse, mutect2, varscan2
- LILRA1 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 65/553 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as rs772814779; called by muse, mutect2, varscan2
- LILRB2 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs754528432, COSV58744319; called by muse, mutect2, varscan2
- LMX1B | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs760533573; called by muse, mutect2, varscan2
- LRRC9 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199739720; called by muse, mutect2, varscan2
- MED12 | c.100-8T>A | Splice Region (SNP) | VAF 38/107 reads (36%) | catalogued as rs199469675, COSV61329462; ClinVar: not provided; called by muse, mutect2, varscan2
- MEGF11 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs538348245, COSV56549683; called by muse, mutect2, varscan2
- MRGPRF | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.936); catalogued as rs1204242017, COSV57996462; called by muse, mutect2, varscan2
- MYCBP2 | c.13159G>A p.D4387N (on ENST00000357337; = p.D4425N on NM_015057.5) | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs941096147; called by muse, mutect2, varscan2
- MYH13 | c.4834C>T p.R1612W | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1397816473; called by muse, mutect2, varscan2
- NFATC1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs924224430; called by muse, mutect2, varscan2
- NKAPL | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as rs1209791311, COSV59198463; called by muse, mutect2, varscan2
- NPAT | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 59/398 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as rs779511551; called by muse, mutect2, varscan2
- OBSL1 | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771774642; called by muse, mutect2, varscan2
- PIMREG | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144086256; called by muse, mutect2, varscan2
- PLEKHA4 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1381531122, COSV54360812; called by muse, mutect2
- PMFBP1 | c.3055G>T p.D1019Y | Missense Mutation (SNP) | VAF 16/88 reads (18%) | PolyPhen possibly damaging (0.713); catalogued as COSV52827553; called by muse, mutect2, varscan2
- POLR3E | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs368901417, COSV55402615; called by muse, mutect2, varscan2
- PPP6R1 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69800012; called by muse, mutect2, varscan2
- SLC12A9 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs756324052, COSV51931057, COSV51931164; called by muse, mutect2, varscan2
- SLC4A3 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.119); catalogued as rs778676773; called by muse, mutect2, varscan2
- SPTBN1 | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770119750; called by muse, mutect2, varscan2
- STOX2 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs372362393; called by muse, mutect2, varscan2
- SV2B | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs779737104, COSV57702006; called by muse, mutect2, varscan2
- SYNE1 | c.19423C>T p.R6475* (on ENST00000367255 / NM_182961.4; = p.R6404* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 33/183 reads (18%) | catalogued as rs1258745040; called by muse, mutect2, varscan2
- SYNM | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539280580; called by muse, mutect2, varscan2
- SYT10 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1242285420, COSV57339451; called by muse, mutect2, varscan2
- TMEM151A | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59174522; called by muse, mutect2, varscan2
- UBE3D | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761884607; called by muse, mutect2, varscan2
- VWA7 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as rs1172289869; called by muse, mutect2, varscan2
- WDR64 | c.1861A>G p.I621V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs779862935; called by muse, mutect2
- ZNF469 | c.5279G>A p.R1760Q (on ENST00000437464; = p.R1788Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 70/480 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs763345014, COSV101458833; called by mutect2, varscan2
- BCOR | c.4652_4653del p.S1551Lfs*4 (on ENST00000378444 / NM_001123385.2; = p.S1517Lfs*4 on NM_017745.6) | Frame Shift Del (DEL) | VAF 68/201 reads (34%) | called by pindel, varscan2
- DCHS2 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- EPHA3 | c.2690+1G>T p.X897_splice | Splice Site (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2
- FCGBP | c.10190G>A p.R3397H | Missense Mutation (SNP) | VAF 104/565 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GBF1 | c.3742C>G p.H1248D (on ENST00000369983 / NM_001377137.1; = p.H1247D on NM_004193.3) | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GNG2 | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HEPHL1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- HK2 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HUWE1 | c.12697A>G p.I4233V | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ITGA4 | c.2073+1G>T p.X691_splice | Splice Site (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- JMJD1C | c.3626T>G p.F1209C | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM4A | c.1843_1844del p.V615Qfs*2 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by pindel, varscan2
- LPCAT1 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 57/329 reads (17%) | called by muse, mutect2, varscan2
- NCAPD2 | c.262+1G>A p.X88_splice | Splice Site (SNP) | VAF 25/215 reads (12%) | called by muse, mutect2, varscan2
- NLGN2 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 91/495 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PIK3C2G | c.4002A>T p.E1334D (on ENST00000676171; = p.E1293D on NM_004570.5) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.167); called by muse, mutect2
- PLCB4 | c.1687_1690dup p.Y564Sfs*29 | Frame Shift Ins (INS) | VAF 12/96 reads (13%) | called by mutect2, varscan2
- PXDNL | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- RCOR1 | c.687_694del p.V230Lfs*10 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- ROBO4 | c.1367G>T p.W456L | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2
- SLC13A5 | c.1705T>C p.*569Qext*174 | Nonstop Mutation (SNP) | VAF 32/231 reads (14%) | called by muse, mutect2, varscan2
- SMAD2 | c.838del p.Y280Mfs*3 | Frame Shift Del (DEL) | VAF 48/192 reads (25%) | called by mutect2, pindel, varscan2
- SRRM4 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SSC5D | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SYT11 | c.516dup p.A173Sfs*17 | Frame Shift Ins (INS) | VAF 32/179 reads (18%) | called by mutect2, pindel, varscan2
- TFAP2D | c.1045C>A p.Q349K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- TSPAN2 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WSCD2 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZBTB45 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ZNF585B | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- ACAN | c.345C>T p.D115= | Silent (SNP) | VAF 67/485 reads (14%) | catalogued as rs532105305, COSV100719507; called by muse, mutect2, varscan2
- ASPN | c.798A>G p.E266= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- C3 | c.2988C>T p.D996= | Silent (SNP) | VAF 16/173 reads (9%) | catalogued as rs774319618; called by muse, mutect2
- CLCN2 | c.2223G>A p.L741= | Silent (SNP) | VAF 19/401 reads (5%) | called by muse, mutect2
- COL12A1 | c.5988G>A p.P1996= | Silent (SNP) | VAF 15/206 reads (7%) | catalogued as rs767451558, COSV59409770; called by muse, mutect2
- COL5A3 | c.4662G>T p.L1554= | Silent (SNP) | VAF 38/215 reads (18%) | called by muse, mutect2, varscan2
- COL6A3 | c.4059C>T p.D1353= | Silent (SNP) | VAF 93/625 reads (15%) | catalogued as rs765355858, COSV55103114; called by muse, mutect2, varscan2
- CORO2A | c.1299G>A p.L433= | Silent (SNP) | VAF 65/346 reads (19%) | called by muse, mutect2, varscan2
- CPN2 | c.1305G>T p.V435= | Silent (SNP) | VAF 111/711 reads (16%) | called by muse, mutect2, varscan2
- CRYGA | c.225G>A p.S75= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as rs137892904; called by muse, mutect2, varscan2
- DACT1 | c.2139C>T p.Y713= | Silent (SNP) | VAF 39/235 reads (17%) | catalogued as rs778935261, COSV60019654; called by muse, mutect2, varscan2
- DCDC1 | c.2754C>T p.S918= (on ENST00000597505 / NM_001367979.1; = p.S25= on NM_020869.3) | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- FREM2 | c.741C>T p.G247= | Silent (SNP) | VAF 76/387 reads (20%) | catalogued as rs1489880344, COSV54837628; called by muse, varscan2
- GART | c.2259C>T p.I753= | Silent (SNP) | VAF 43/237 reads (18%) | called by muse, mutect2, varscan2
- GBGT1 | c.795C>T p.F265= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs1399259047; called by muse, mutect2, varscan2
- GRIA4 | c.816A>C p.V272= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- HLA-DOA | c.126C>T p.Y42= | Silent (SNP) | VAF 53/346 reads (15%) | catalogued as COSV57713667; called by muse, mutect2, varscan2
- HOXB6 | c.627C>T p.S209= | Silent (SNP) | VAF 103/463 reads (22%) | catalogued as COSV53312113, COSV53313502; called by muse, mutect2, varscan2
- KAT6A | c.4014G>A p.R1338= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- LOXHD1 | c.4956C>T p.I1652= | Silent (SNP) | VAF 50/254 reads (20%) | catalogued as rs187103862; called by muse, mutect2, varscan2
- LRP2 | c.114G>T p.G38= | Silent (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- MMP17 | c.639C>T p.P213= | Silent (SNP) | VAF 60/393 reads (15%) | catalogued as rs138755759, COSV100861989; called by muse, mutect2, varscan2
- NDUFB4 | c.54C>T p.L18= | Silent (SNP) | VAF 56/343 reads (16%) | catalogued as COSV51743092; called by muse, mutect2, varscan2
- NECAB2 | c.741T>C p.G247= | Silent (SNP) | VAF 32/263 reads (12%) | called by muse, mutect2, varscan2
- NYAP2 | c.1371C>T p.Y457= | Silent (SNP) | VAF 80/542 reads (15%) | catalogued as rs750472721, COSV55998444; called by muse, mutect2, varscan2
- OTOF | c.2649C>T p.C883= (on ENST00000272371 / NM_194248.3; = p.C136= on NM_004802.4) | Silent (SNP) | VAF 57/310 reads (18%) | catalogued as rs397515593, CM083001; called by muse, mutect2, varscan2
- PCDH1 | c.2526A>C p.P842= | Silent (SNP) | VAF 110/506 reads (22%) | called by mutect2, varscan2
- PCLO | c.10009T>C p.L3337= | Silent (SNP) | VAF 95/480 reads (20%) | called by muse, mutect2, varscan2
- PIEZO2 | c.2505G>A p.P835= | Silent (SNP) | VAF 32/171 reads (19%) | catalogued as rs781706412, COSV100127726; called by muse, mutect2, varscan2
- RD3 | c.417G>A p.T139= | Silent (SNP) | VAF 50/309 reads (16%) | catalogued as rs1232346364, COSV100879196; called by muse, mutect2, varscan2
- RYR1 | c.13164C>T p.S4388= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1160207470; called by muse, varscan2
- SLC17A9 | c.798C>T p.F266= | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as rs538069374, COSV64847275; called by muse, mutect2, varscan2
- SLC4A5 | c.1926C>T p.T642= | Silent (SNP) | VAF 51/325 reads (16%) | catalogued as COSV61032860; called by muse, mutect2, varscan2
- SOX18 | c.366G>A p.A122= | Silent (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- SOX30 | c.42G>A p.P14= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1406095890; called by muse, mutect2, varscan2
- SYNE4 | c.1104G>C p.V368= | Silent (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
- TGIF2LY | c.177C>T p.A59= | Silent (SNP) | VAF 69/226 reads (31%) | called by muse, mutect2, varscan2
- USP17L1 | c.1056C>T p.A352= | Silent (SNP) | VAF 99/711 reads (14%) | catalogued as rs762893851; called by muse, mutect2, varscan2
- WDR87 | c.6612G>A p.K2204= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- ZNF626 | c.483C>T p.N161= | Silent (SNP) | VAF 28/186 reads (15%) | catalogued as rs567636048, COSV74129659; called by muse, mutect2, varscan2
- ABCA4 | c.6282+229G>A | Intron (SNP) | VAF 63/472 reads (13%) | catalogued as rs1323199774; called by muse, mutect2, varscan2
- CATSPER2 | c.717+49G>T | Intron (SNP) | VAF 30/207 reads (14%) | called by mutect2, varscan2
- CSNK1E | c.*32+38C>T | Intron (SNP) | VAF 13/78 reads (17%) | catalogued as rs894106618; called by muse, mutect2, varscan2
- DEPDC5 | c.1870+2396C>T | Intron (SNP) | VAF 28/170 reads (16%) | catalogued as COSV56696825, COSV56705141; called by muse, mutect2, varscan2
- EYS | c.1767-7278G>A | Intron (SNP) | VAF 54/309 reads (17%) | catalogued as rs781690350, COSV65459563; called by muse, mutect2, varscan2
- FAM227B | c.1013-24625G>T | Intron (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- GRM3 | c.-178G>A | 5'UTR (SNP) | VAF 37/248 reads (15%) | catalogued as rs751231935; called by muse, mutect2, varscan2
- GUSBP1 | n.180-10307G>T | Intron (SNP) | VAF 36/984 reads (4%) | called by muse, mutect2
- MIR663A | n.10G>A | RNA (SNP) | VAF 4/28 reads (14%) | catalogued as rs1234765502; called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46109765 G>T | 5'Flank (SNP) | VAF 62/308 reads (20%) | called by muse, mutect2, varscan2
- NARF | c.769+1051G>A | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as rs1009425522; called by muse, mutect2, varscan2
- NKX2-1 | chr14:36520137 C>T | 5'Flank (SNP) | VAF 31/308 reads (10%) | catalogued as rs749414192, COSV100702024; called by muse, mutect2, varscan2
- NR1I2 | c.332-10G>T | Intron (SNP) | VAF 29/187 reads (16%) | called by muse, mutect2, varscan2
- NRG1 | c.700+640G>A | Intron (SNP) | VAF 23/159 reads (14%) | catalogued as rs745499338, COSV55149762; called by muse, mutect2, varscan2
- OR4F13P | n.1243A>T | RNA (SNP) | VAF 30/135 reads (22%) | catalogued as rs1426440693; called by muse, mutect2, varscan2
- SP110 | c.1591-47G>A | Intron (SNP) | VAF 40/288 reads (14%) | catalogued as rs576544273; called by muse, mutect2, varscan2
- SPATA13 | c.-222-26129C>T | Intron (SNP) | VAF 34/296 reads (11%) | catalogued as rs372376733, COSV66069563; called by muse, mutect2, varscan2
- TACC1 | c.1960+17G>A | Intron (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- USH1C | c.1284+7629G>A | Intron (SNP) | VAF 33/207 reads (16%) | catalogued as rs201104489; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- VEPH1 | c.529+299C>T | Intron (SNP) | VAF 7/167 reads (4%) | catalogued as rs1230830967; called by muse, mutect2
